Somatic mutation profile of tumor specimen TCGA-14-0871-01A (aliquot TCGA-14-0871-01A-01W-0424-08) from TCGA case TCGA-14-0871, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.0 years (27,387 days).
Specimen TCGA-14-0871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 896c8e4c-4a7a-4a01-af20-aee0203c46f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0871-10A (Blood Derived Normal), aliquot TCGA-14-0871-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1307df0a-7e36-48c5-9bcc-5dd809293e30

The open-access MAF lists 152 somatic variants for this specimen: 130 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Frame Shift Ins 41, Silent 19, Nonsense Mutation 8, In Frame Ins 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSCL2 | c.782dup p.I262Hfs*12 | Frame Shift Ins (INS) | VAF 14/122 reads (11%) | catalogued as rs749890533; ClinVar: pathogenic; called by mutect2, varscan2
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 1219/1285 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 152/826 reads (18%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 251/1728 reads (15%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 16/118 reads (14%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- RSPO4 | c.98dup p.N34Qfs*63 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs768138495; ClinVar: pathogenic; called by pindel, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 65/406 reads (16%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TMPRSS6 | c.1786dup p.A596Gfs*5 | Frame Shift Ins (INS) | VAF 11/64 reads (17%) | catalogued as rs767094129; ClinVar: pathogenic; called by mutect2, varscan2
- AGXT2 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51484176; called by muse, mutect2, varscan2
- ANK1 | c.1369C>A p.L457I | Missense Mutation (SNP) | VAF 40/686 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as rs1426654334; called by muse, mutect2
- ATN1 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); catalogued as rs1555144216; called by muse, mutect2
- ATR | c.1372C>A p.Q458K | Missense Mutation (SNP) | VAF 5/137 reads (4%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as COSV99052466; called by muse, mutect2
- C3orf38 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 44/72 reads (61%) | catalogued as COSV59627722; called by muse, mutect2, varscan2
- CCDC178 | c.1075A>T p.I359L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV55763950; called by mutect2, varscan2
- CDH10 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 48/1252 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV52595964; called by muse, mutect2
- CDK12 | c.4382dup p.T1463Nfs*50 (on ENST00000447079 / NM_016507.4; = p.T1454Nfs*50 on NM_015083.3) | Frame Shift Ins (INS) | VAF 26/208 reads (13%) | catalogued as rs760014508; called by mutect2, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 41/255 reads (16%) | catalogued as rs747299117; called by mutect2, varscan2
- CIITA | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 56/988 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV60854161; called by muse, mutect2
- CKAP2L | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442633705; called by muse, mutect2
- CPO | c.600A>T p.Q200H | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55938951; called by muse, mutect2, varscan2
- CSF3R | c.1404dup p.S469Qfs*5 | Frame Shift Ins (INS) | VAF 34/298 reads (11%) | catalogued as rs747437399; called by mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 175/1444 reads (12%) | catalogued as rs756924682; called by mutect2, varscan2
- CTSF | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as COSV59747781; called by muse, mutect2, varscan2
- DDB1 | c.685dup p.A229Gfs*15 | Frame Shift Ins (INS) | VAF 22/166 reads (13%) | catalogued as rs757472327; called by mutect2, varscan2
- DRD3 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55679149, COSV55679958; called by mutect2, varscan2
- EARS2 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 14/427 reads (3%) | catalogued as COSV71942900; called by muse, mutect2
- FANCM | c.1031A>T p.N344I | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs754308697, COSV57498269; called by muse, mutect2, varscan2
- FIGN | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs367860574; called by muse, mutect2, varscan2
- FUCA1 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 262/478 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as rs1170852060, COSV65698786; called by muse, varscan2
- FUCA1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65698792; called by muse, varscan2
- GIMAP5 | c.884T>A p.L295H | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV57529761, COSV57529909; called by muse, mutect2, varscan2
- GPC6 | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 102/105 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1360308566, COSV65502385; called by muse, mutect2, varscan2
- HIPK1 | c.3202dup p.R1068Pfs*83 (on ENST00000369558 / NM_001369806.1; = p.R674Pfs*83 on NM_181358.2) | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs1378844955; called by pindel, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 120/970 reads (12%) | catalogued as rs745545309; called by mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 13/108 reads (12%) | catalogued as rs751926247; called by mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 20/123 reads (16%) | catalogued as rs774820321; called by mutect2, varscan2
- KRTAP10-9 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV59954656; called by muse, mutect2, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 20/142 reads (14%) | catalogued as rs750932259; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 41/204 reads (20%) | catalogued as rs757410385; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 15/78 reads (19%) | catalogued as rs777328830; called by mutect2, varscan2
- MARCHF3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750922022, COSV58037557; called by muse, mutect2, varscan2
- MEGF6 | c.1760dup p.V589Cfs*5 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | catalogued as rs760635494; called by mutect2, pindel
- MFSD9 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 85/494 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51492902; called by muse, mutect2, varscan2
- MRC2 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV100316610; called by mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 26/200 reads (13%) | catalogued as rs761123152; called by mutect2, varscan2
- NEFL | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55336934, COSV55337619; called by muse, mutect2, varscan2
- NF1 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 438/460 reads (95%) | catalogued as CM950846, COSV62195945; called by muse, mutect2, varscan2
- NFE2 | c.661dup p.E221Gfs*7 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs770975576; called by pindel, varscan2
- NR1H3 | c.855C>A p.D285E | Missense Mutation (SNP) | VAF 28/842 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101269822; called by muse, mutect2
- NR5A2 | c.875G>C p.S292T (on ENST00000367362 / NM_205860.3; = p.S246T on NM_003822.5) | Missense Mutation (SNP) | VAF 402/965 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52646436; called by muse, mutect2, varscan2
- NRXN1 | c.1832A>T p.D611V | Missense Mutation (SNP) | VAF 283/508 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV58440676; called by muse, varscan2
- NUP62CL | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65235458; called by muse, mutect2, varscan2
- OR2T3 | c.580T>C p.C194R | Missense Mutation (SNP) | VAF 244/463 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369559398; called by muse, mutect2, varscan2
- OR5AR1 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 120/371 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV57253083; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 48/350 reads (14%) | catalogued as rs780916980; called by mutect2, varscan2
- OVGP1 | c.1054dup p.A352Gfs*10 | Frame Shift Ins (INS) | VAF 82/706 reads (12%) | catalogued as rs763064364; called by mutect2, varscan2
- PCDHGC3 | c.2050dup p.R684Pfs*41 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs764598056; called by pindel, varscan2
- PCYT1A | c.519T>G p.Y173* | Nonsense Mutation (SNP) | VAF 32/220 reads (15%) | catalogued as COSV53056525; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | catalogued as rs749326031; called by mutect2, varscan2
- PIGT | c.1043dup p.V349Sfs*99 | Frame Shift Ins (INS) | VAF 23/210 reads (11%) | catalogued as rs749895437; called by mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 164/1210 reads (14%) | catalogued as rs749506841; called by mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 30/174 reads (17%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PTPRD | c.4300G>A p.E1434K | Missense Mutation (SNP) | VAF 283/850 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61932965, COSV61935427; called by muse, mutect2, varscan2
- PUM3 | c.1023dup p.K342Qfs*8 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs749329036; called by pindel, varscan2
- RAB24 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs755530764, COSV57462923; called by muse, mutect2, varscan2
- SALL2 | c.1586dup p.G530Rfs*3 | Frame Shift Ins (INS) | VAF 136/1079 reads (13%) | catalogued as rs755171367; called by mutect2, varscan2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | catalogued as rs35259575; called by mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 128/714 reads (18%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC28A3 | c.159T>A p.D53E | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66152303; called by muse, mutect2, varscan2
- SLC2A14 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 109/184 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.349); catalogued as COSV61585777; called by muse, mutect2, varscan2
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 38/262 reads (15%) | catalogued as rs747624971; called by mutect2, varscan2
- SYNE1 | c.2528G>C p.R843P (on ENST00000367255 / NM_182961.4; = p.R850P on NM_033071.3) | Missense Mutation (SNP) | VAF 58/423 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54927660; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 59/337 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 39/224 reads (17%) | catalogued as rs782753958; called by mutect2, varscan2
- TMEM132B | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV54747361, COSV54774585; called by muse, varscan2
- TP53 | c.902dup p.G302Rfs*4 | Frame Shift Ins (INS) | VAF 284/511 reads (56%) | catalogued as COSV53177081; called by pindel, varscan2
- TRIM17 | c.821dup p.T275Nfs*14 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs758372115; called by mutect2, varscan2
- TTBK1 | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 199/615 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52489079; called by muse, mutect2, varscan2
- TUBG2 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1157142160, COSV52216984; called by muse, mutect2, varscan2
- VANGL1 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 38/860 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV59620657; called by muse, mutect2
- WDR88 | c.1023T>A p.F341L | Missense Mutation (SNP) | VAF 506/1821 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV63450871; called by muse, mutect2, varscan2
- WIF1 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV54130211; called by muse, mutect2
- WNK4 | c.1814C>A p.P605H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV55902241; called by mutect2, varscan2
- WWP2 | c.2600T>C p.F867S | Missense Mutation (SNP) | VAF 177/197 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63123767; called by muse, mutect2, varscan2
- ABCA10 | c.1766C>A p.A589D | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATP7A | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1orf116 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- CMYA5 | c.10448G>C p.S3483T | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- COL6A3 | c.8563C>A p.Q2855K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CSMD3 | c.9556G>T p.G3186* (on ENST00000297405 / NM_001363185.1; = p.G3017* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 36/753 reads (5%) | called by muse, mutect2
- DCC | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 64/984 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- DDIT3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.357); called by muse, mutect2
- DSP | c.6810G>C p.Q2270H | Missense Mutation (SNP) | VAF 73/830 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- FBXO38 | c.2285C>G p.A762G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLT3 | c.1820G>T p.R607I | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FREM2 | c.6943G>C p.G2315R | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GAS2L2 | c.1877G>C p.R626T | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPM6A | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 133/457 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GUCY2F | c.3250C>T p.H1084Y | Missense Mutation (SNP) | VAF 40/508 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LARP4B | c.2202dup p.K735Qfs*41 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- MARCHF6 | c.2295dup p.G766Wfs*25 | Frame Shift Ins (INS) | VAF 20/166 reads (12%) | called by mutect2, pindel, varscan2
- MARVELD3 | c.701dup p.I235Hfs*14 | Frame Shift Ins (INS) | VAF 9/81 reads (11%) | called by mutect2, pindel
- MAST3 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 178/462 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by mutect2, varscan2
- MBTPS1 | c.1546G>T p.V516F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MTF1 | c.905C>G p.T302S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.038); called by muse, mutect2
- MTOR | c.4008G>T p.E1336D | Missense Mutation (SNP) | VAF 212/3642 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); called by muse, mutect2
- NF1 | c.4572C>A p.S1524R (on ENST00000358273 / NM_001042492.3; = p.S1503R on NM_000267.3) | Missense Mutation (SNP) | VAF 76/410 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NLE1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- OR13C3 | c.306C>A p.C102* | Nonsense Mutation (SNP) | VAF 9/236 reads (4%) | called by muse, mutect2
- PAPPA2 | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 118/1676 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2
- PARS2 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 63/1371 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- PGS1 | c.1467T>G p.F489L | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, varscan2
- PLCG2 | c.2466C>A p.N822K | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLEKHM2 | c.1253_1254insGCGAGACCAGCCCCTCAA p.L417_N418insKRDQPL | In Frame Ins (INS) | VAF 53/275 reads (19%) | called by pindel, varscan2*
- POU4F2 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PPARGC1B | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PRSS23 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2
- PTPRB | c.3824C>A p.T1275K | Missense Mutation (SNP) | VAF 30/772 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2
- QPRT | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 47/792 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.785); called by muse, mutect2
- RANBP17 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL2 | c.3402C>A p.F1134L | Missense Mutation (SNP) | VAF 80/978 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC26A9 | c.1430G>C p.S477T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- SLIT2 | c.4030G>C p.G1344R | Missense Mutation (SNP) | VAF 151/366 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- STK40 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.491); called by mutect2, varscan2
- TCP11 | c.1063G>T p.V355L (on ENST00000512012; = p.V293L on NM_018679.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.094); called by muse, mutect2
- TTN | c.53863G>T p.A17955S (on ENST00000591111; = p.A10531S on NM_003319.4) | Missense Mutation (SNP) | VAF 76/810 reads (9%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- TTN | c.53077G>T p.V17693F (on ENST00000591111; = p.V10269F on NM_003319.4) | Missense Mutation (SNP) | VAF 36/316 reads (11%) | PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- UBE2NL | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 86/94 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2
- UPF1 | c.1142T>C p.L381P (on ENST00000599848 / NM_001297549.2; = p.L370P on NM_002911.4) | Missense Mutation (SNP) | VAF 42/1470 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- ZNF285 | c.1507C>G p.Q503E | Missense Mutation (SNP) | VAF 250/770 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, varscan2
- ACTN1 | c.1785C>T p.I595= | Silent (SNP) | VAF 221/2073 reads (11%) | catalogued as COSV51989211; called by muse, mutect2, varscan2
- ARHGAP25 | c.1176T>C p.S392= (on ENST00000409202 / NM_001007231.3; = p.S384= on NM_014882.3) | Silent (SNP) | VAF 73/609 reads (12%) | catalogued as COSV54899894; called by muse, mutect2, varscan2
- CENPU | c.756T>C p.N252= | Silent (SNP) | VAF 93/294 reads (32%) | catalogued as rs1396758809, COSV55656760; called by muse, mutect2, varscan2
- FANCD2 | c.1362C>A p.G454= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- GABRP | c.273C>A p.R91= | Silent (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- GABRQ | c.222G>A p.L74= | Silent (SNP) | VAF 17/364 reads (5%) | catalogued as rs1556818218, COSV64781131; called by muse, mutect2
- LMAN2L | c.387C>G p.G129= | Silent (SNP) | VAF 45/748 reads (6%) | catalogued as COSV53840813; called by muse, mutect2
- NDST2 | c.168C>T p.S56= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- NFATC4 | c.2484C>A p.S828= | Silent (SNP) | VAF 31/282 reads (11%) | catalogued as rs1439279067; called by muse, mutect2, varscan2
- OR2T33 | c.387A>G p.R129= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- OSBP | c.765C>T p.I255= | Silent (SNP) | VAF 66/194 reads (34%) | catalogued as rs781114937, COSV55661287, COSV55664519; called by muse, mutect2, varscan2
- PAK1IP1 | c.348G>T p.L116= | Silent (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- SCARB1 | c.720G>A p.L240= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV55544686; called by muse, mutect2, varscan2
- SDCBP2 | c.201G>T p.L67= | Silent (SNP) | VAF 74/1464 reads (5%) | called by muse, mutect2
- TMEM121 | c.192C>A p.G64= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs782090105; called by mutect2, varscan2
- TUBA3E | c.444G>C p.G148= | Silent (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- UBE2NL | c.285G>A p.K95= | Silent (SNP) | VAF 87/96 reads (91%) | called by muse, mutect2
- ZNF470 | c.660A>G p.Q220= | Silent (SNP) | VAF 83/619 reads (13%) | catalogued as COSV57967937; called by muse, mutect2, varscan2
- ZNF625 | c.654A>C p.P218= | Silent (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- MIR1208 | chr8:128150186 ins G | RNA (INS) | VAF 26/218 reads (12%) | catalogued as rs745702657; called by mutect2, varscan2
- PPP3R1 | chr2:68253019 C>A | 5'Flank (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- ST6GALNAC6 | c.*74dup | 3'UTR (INS) | VAF 24/202 reads (12%) | catalogued as rs747612913; called by mutect2, varscan2
